Somatic mutation profile of tumor specimen 0DQDDH from CCDI case PBCDNI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 12.7 years (4,646 days).
Specimen 0DQDDH: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 17183cef-1e59-4473-a824-8b8c8c615adb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQDDP (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d24439d8-13f0-4af5-9781-3fc5dc80aabb

The open-access MAF lists 20 somatic variants for this specimen: 9 protein-altering or splice-affecting, 3 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Intron 5, Silent 3, 5'UTR 2, 5'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CIP2A | c.106A>G p.I36V | Missense Mutation (SNP) | VAF 97/377 reads (26%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as rs1326264994; called by muse, mutect2, varscan2
- MYH1 | c.2341C>T p.R781* | Nonsense Mutation (SNP) | VAF 66/1014 reads (7%) | catalogued as rs750331285, COSV56844274, COSV56856511; called by muse, mutect2
- PCDHAC2 | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 151/355 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0.097); catalogued as rs1332345482; called by muse, mutect2, varscan2
- SLAMF7 | c.550T>A p.W184R | Missense Mutation (SNP) | VAF 25/428 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs141021747; called by muse, mutect2
- TECTA | c.2047G>A p.V683I | Missense Mutation (SNP) | VAF 80/1046 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as rs928587604, COSV99881722; called by muse, mutect2
- ATP1A3 | c.1130G>A p.C377Y (on ENST00000545399 / NM_001256214.2; = p.C364Y on NM_152296.5) | Missense Mutation (SNP) | VAF 210/797 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CEP120 | c.1048G>C p.E350Q | Missense Mutation (SNP) | VAF 22/622 reads (4%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2
- LSM14A | c.272C>T p.P91L | Missense Mutation (SNP) | VAF 173/631 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- STAB2 | c.4963A>G p.M1655V | Missense Mutation (SNP) | VAF 86/914 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.334); called by muse, mutect2
- CACNG8 | c.639C>T p.F213= | Silent (SNP) | VAF 257/880 reads (29%) | called by muse, mutect2, varscan2
- FLNB | c.5916C>T p.G1972= | Silent (SNP) | VAF 60/742 reads (8%) | catalogued as rs112942586; ClinVar: likely benign / uncertain significance; called by muse, mutect2
- PLCL1 | c.936C>A p.T312= | Silent (SNP) | VAF 396/933 reads (42%) | catalogued as COSV70821511; called by muse, mutect2, varscan2
- AC046195.1 | n.680+5952G>C | Intron (SNP) | VAF 62/1446 reads (4%) | called by muse, mutect2
- CCAR2 | c.2074-58C>T | Intron (SNP) | VAF 20/482 reads (4%) | catalogued as rs1402589236; called by muse, mutect2
- FBRS | chr16:30659834 G>A | 5'Flank (SNP) | VAF 150/289 reads (52%) | called by muse, mutect2, varscan2
- MOG | c.593-104C>A | Intron (SNP) | VAF 33/424 reads (8%) | called by muse, mutect2
- PROP1 | c.-1C>A | 5'UTR (SNP) | VAF 23/259 reads (9%) | called by muse, mutect2
- SLC18A2 | c.-15-15G>A | Intron (SNP) | VAF 10/150 reads (7%) | called by muse, mutect2
- ZFP36L1 | c.-184C>G | 5'UTR (SNP) | VAF 21/309 reads (7%) | called by muse, mutect2
- ZFYVE16 | c.3607+79C>T | Intron (SNP) | VAF 8/84 reads (10%) | called by muse, varscan2
